Somatic mutation profile of tumor specimen TCGA-DU-A76R-01A (aliquot TCGA-DU-A76R-01A-11D-A32B-08) from TCGA case TCGA-DU-A76R, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 51.9 years (18,939 days).
Specimen TCGA-DU-A76R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4620b1e-9217-4996-97db-7f8882724a98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A76R-10A (Blood Derived Normal), aliquot TCGA-DU-A76R-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a6e6d7d-7d80-4879-9438-1bd279216bd8

The open-access MAF lists 44 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 30, Silent 11, Splice Region 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 20/55 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 38/89 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1057519933, COSV55878486, COSV56029794; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AHNAK | c.3335C>T p.A1112V | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as COSV99947810; called by muse, mutect2, varscan2
- ARHGAP10 | c.2255G>A p.G752E | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100331304; called by muse, mutect2, varscan2
- ASB5 | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs545829322, COSV56668638; called by muse, mutect2, varscan2
- CCDC68 | c.560A>G p.Q187R | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.03); catalogued as rs1245104089, COSV100491854; called by muse, mutect2, varscan2
- CHST15 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs559698999, COSV100655170; called by muse, varscan2
- CLTC | c.1964T>G p.F655C | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99292380; called by muse, mutect2, varscan2
- DNAH7 | c.7506G>A p.Q2502= | Splice Region (SNP) | VAF 19/45 reads (42%) | catalogued as COSV100415491; called by muse, mutect2, varscan2
- FOXI1 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100089407; called by muse, mutect2, varscan2
- GRM3 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as rs768886254, COSV64480283; called by muse, mutect2, varscan2
- IFT140 | c.2012G>A p.R671H | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.161); catalogued as rs1372026395, COSV68489140; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDM6B | c.748C>G p.P250A | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.351); catalogued as COSV99641610; called by muse, mutect2, varscan2
- KTN1 | c.832+2T>C p.X278_splice | Splice Site (SNP) | VAF 15/52 reads (29%) | catalogued as COSV68025938; called by muse, mutect2, varscan2
- LARP7 | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100134957, COSV100135175; called by muse, mutect2, varscan2
- MYH15 | c.5032G>A p.D1678N | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); catalogued as rs1560317075, COSV56306390; called by muse, mutect2
- MYH2 | c.3541C>T p.R1181C | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs201768483, COSV55435133; called by muse, mutect2, varscan2
- NCF1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs1563002882, COSV99194289; called by muse, mutect2, varscan2
- NISCH | c.3767C>T p.T1256M | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs1027561537, COSV58740103; called by muse, mutect2, varscan2
- NRCAM | c.2387C>T p.T796I (on ENST00000379028 / NM_001371124.1; = p.T780I on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.609); catalogued as COSV100694802; called by muse, mutect2, varscan2
- PAPPA2 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1404998147, COSV100866822; called by muse, mutect2, varscan2
- PRPF40B | c.1738G>A p.E580K (on ENST00000380281; = p.E567K on NM_012272.3) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV99526406; called by muse, mutect2, varscan2
- RASGRF1 | c.2695G>A p.A899T | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV101174534; called by muse, mutect2, varscan2
- SOX5 | c.1381C>G p.Q461E | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV100507073; called by muse, mutect2, varscan2
- SPTBN5 | c.7768C>T p.R2590C | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs375028833; called by muse, mutect2, varscan2
- SRM | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs760693030, COSV100978954; called by muse, mutect2, varscan2
- STAMBPL1 | c.767G>A p.S256N | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.474); catalogued as COSV100904963; called by muse, mutect2, varscan2
- TMEM45B | c.125A>C p.Y42S | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99859388; called by muse, mutect2
- TRAF5 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs377497907; called by muse, mutect2, varscan2
- WDR72 | c.2221G>A p.A741T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.058); catalogued as COSV100854568; called by mutect2, varscan2
- WFIKKN2 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.16); catalogued as COSV100259895, COSV60959209; called by muse, mutect2, varscan2
- ZNF563 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs113773973; called by muse, mutect2, varscan2
- CCL16 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CFHR4 | c.69T>C p.C23= (on ENST00000367416 / NM_001201551.2; = p.C24= on NM_006684.5) | Silent (SNP) | VAF 6/109 reads (6%) | catalogued as COSV52225072, COSV99260620; called by muse, mutect2
- CLEC1B | c.621C>T p.F207= | Silent (SNP) | VAF 34/144 reads (24%) | catalogued as COSV100046089, COSV53725785; called by muse, mutect2, varscan2
- COMMD5 | c.135G>A p.R45= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as COSV100521888; called by muse, mutect2, varscan2
- GPR174 | c.636G>A p.L212= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV99338168; called by muse, mutect2, varscan2
- ITPKB | c.456G>A p.A152= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as COSV55259273; called by muse, mutect2, varscan2
- OR13C8 | c.777C>T p.Y259= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs753314500, COSV58612719, COSV99080311; called by muse, mutect2, varscan2
- SAMD9 | c.2061C>T p.G687= | Silent (SNP) | VAF 27/160 reads (17%) | catalogued as COSV101180272; called by muse, mutect2, varscan2
- SFSWAP | c.2157G>A p.T719= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs202167599, COSV55524405; called by muse, mutect2, varscan2
- SGK1 | c.1281G>A p.T427= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs372966158; called by muse, mutect2, varscan2
- SLITRK3 | c.846C>A p.P282= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV53845975, COSV53846313; called by muse, mutect2, varscan2
- ZNF574 | c.1650C>G p.P550= | Silent (SNP) | VAF 54/80 reads (68%) | catalogued as COSV99726178, COSV99726203; called by muse, mutect2, varscan2
